TCGA case TCGA-CJ-4638 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: MD Anderson Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/06197e26-3cb0-4bd0-a6e8-dd9af5047c6a

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 46 years; Vital status: Dead; Days to death: 431 days (1.2 years).

Diagnoses (2)
1. Clear cell adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 46.8 years (17,110 days); Year of diagnosis: 2004; AJCC pathologic T: T3a; AJCC pathologic N: N1; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Tumor grade: G4; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 2; Lymph nodes tested: 3.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Initial disease status: Progressive Disease; Days to treatment start: 70 days; Days to treatment end: 252 days; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Initial disease status: Progressive Disease; Days to treatment start: 70 days; Days to treatment end: 160 days; Number of cycles: 5; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Palliative; Days to treatment start: 160 days; Days to treatment end: 192 days; Course number: 1; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Recombinant Interleukin-2; Initial disease status: Progressive Disease; Days to treatment start: 192 days; Days to treatment end: 221 days; Route of administration: Subcutaneous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 252 days; Days to treatment end: 281 days; Route of administration: Oral.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 47.0 years (17,180 days); Days to diagnosis: 70 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Surgery, NOS to Locoregional Site; Surgery, NOS to Distant Site.

Follow-up (3 entries)
- Day 70 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 431 days (1.2 years); Disease response: With Tumor.
- ECOG performance status: 0; Timepoint: Recurrence/Progression.

Molecular and laboratory tests
- Calcium: Elevated.
- Lactate Dehydrogenase: Normal.
- Platelets: Normal.
- Leukocytes: Normal.
- Hemoglobin: Low.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CJ-4638-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 2; Intermediate dimension: 0.7; Shortest dimension: 0.5.
  Slide TCGA-CJ-4638-01A-02-BS2: Section location: Bottom; Percent tumor cells: 95; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5.
  Slide TCGA-CJ-4638-01A-01-BS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5.
  Slide TCGA-CJ-4638-01A-01-TS1: Section location: Top; Percent tumor cells: 92; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 5.
- Sample TCGA-CJ-4638-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CJ-4638-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 2; Intermediate dimension: 0.7; Shortest dimension: 0.5.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Hemoglobin level: Low; Lymph nodes examined: Yes.
- Drug treatment 1: Pharmaceutical therapy drug name: Gemictiabine; Therapy regimen: Progression.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 2: Pharmaceutical therapy drug name: Avastin; Therapy regimen: Progression.
- Drug treatment 3: Pharmaceutical therapy drug name: interleukin-2; Therapy regimen: Progression.
- Drug treatment 3, Route of administrations: Route of administration: SC.
- Drug treatment 4: Pharmaceutical therapy drug name: 5-fluorouracil; Therapy regimen: Progression.
- Drug treatment 4, Route of administrations: Route of administration: IV.
- Follow-up form: New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: No; Performance status timing: At Recurrence/Progression Of Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 431 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 431 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 70 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CJ-4638-01A-02D-1322-01): tumor purity 0.68, ploidy 1.94, whole-genome doublings 0.
